Somatic mutation profile of tumor specimen TARGET-20-PARGVC-03A (aliquot TARGET-20-PARGVC-03A-01D) from TARGET case TARGET-20-PARGVC, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,802 days).
Specimen TARGET-20-PARGVC-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3b1f43c-2869-4ca0-814c-2783a300ef9e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARGVC-14A (Bone Marrow Normal), aliquot TARGET-20-PARGVC-14A-03D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b0babdc-73aa-4781-af0b-2fa398a5741b

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, In Frame Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 48/132 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPRT | c.3073G>A p.V1025I | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as rs758531464, COSV61967363; called by muse, mutect2, varscan2
- ACTB | c.329_331dup p.L110_N111insM | In Frame Ins (INS) | VAF 6/56 reads (11%) | called by mutect2, pindel
- PPP1R15A | c.1992G>A p.A664= | Silent (SNP) | VAF 46/103 reads (45%) | catalogued as rs186438232; called by muse, varscan2
